Somatic mutation profile of tumor specimen TCGA-OR-A5LG-01A (aliquot TCGA-OR-A5LG-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 46.2 years (16,875 days).
Specimen TCGA-OR-A5LG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd3c25b7-b759-4809-9762-121b4559223b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LG-10A (Blood Derived Normal), aliquot TCGA-OR-A5LG-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4a40c1e-2319-41dc-aa12-b68f50e1c0c6

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 5'UTR 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1A | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as rs1303300427, COSV100146734; called by muse, mutect2, varscan2
- CAPN2 | c.1623G>C p.L541F | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV54337766; called by muse, mutect2, varscan2
- CASR | c.2675G>A p.G892D (on ENST00000490131; = p.G969D on NM_000388.4) | Missense Mutation (SNP) | VAF 152/357 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99064809; called by muse, mutect2, varscan2
- CASS4 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64386759; called by muse, mutect2, varscan2
- MYO5A | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62562151; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by muse, varscan2
- PNN | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs776836815; called by muse, mutect2, varscan2
- SIRPD | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | PolyPhen benign (0.007); catalogued as rs1400718180; called by muse, mutect2
- SVEP1 | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs776439453, COSV52839652; called by muse, mutect2, varscan2
- BCR | c.2320C>G p.P774A | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CYP17A1 | c.1278_1294dup p.Y432Sfs*5 | Nonsense Mutation (INS) | VAF 44/148 reads (30%) | called by mutect2, varscan2
- EEF2 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GPRASP2 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 146/160 reads (91%) | called by muse, mutect2, varscan2
- KAT6A | c.4854G>A p.M1618I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- PDE2A | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN7A | c.3998T>C p.M1333T | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2
- SPTB | c.4813C>A p.L1605I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2
- ARID3B | c.681C>T p.V227= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- DCP1B | c.1767C>G p.L589= | Silent (SNP) | VAF 51/64 reads (80%) | called by muse, mutect2, varscan2
- HYDIN | c.4545C>A p.A1515= | Silent (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.3408C>T p.V1136= | Silent (SNP) | VAF 152/293 reads (52%) | called by muse, mutect2
- TAF1L | c.4842G>A p.E1614= | Silent (SNP) | VAF 97/223 reads (43%) | called by muse, mutect2, varscan2
- CLU | c.-45_-35del | 5'UTR (DEL) | VAF 18/164 reads (11%) | called by mutect2, pindel
- RBM3 | c.-1C>T | 5'UTR (SNP) | VAF 32/33 reads (97%) | catalogued as rs782290803, COSV63202829; called by muse, mutect2, varscan2
- ZNF561 | c.*1C>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
